Somatic mutation profile of tumor specimen CUPP-B38P-TTM1-A (aliquot CUPP-B38P-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38P, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 64.8 years (23,670 days).
Specimen CUPP-B38P-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b19bbe8-003a-4424-ba4f-593e4bf6f79c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38P-NB1-A (Blood Derived Normal), aliquot CUPP-B38P-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c55fd3ae-f2aa-4d9c-a51a-2eefdb38cb4f

The open-access MAF lists 722 somatic variants for this specimen: 553 protein-altering or splice-affecting, 130 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 479, Silent 130, Nonsense Mutation 46, Intron 23, Frame Shift Del 15, Frame Shift Ins 8, 3'UTR 5, 5'Flank 4, Splice Region 4, 5'UTR 3, RNA 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as rs121918253, CM941072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PITX2 | c.410G>C p.R137P (on ENST00000354925 / NM_001204397.1; = p.R144P on NM_000325.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs104893859, CM961114; ClinVar: pathogenic; called by mutect2, varscan2
- SMAD4 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767367, COSV61685859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4223G>A p.W1408* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as CM990047; called by muse, mutect2, varscan2
- ABCB1 | c.2561G>A p.G854D | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55954141; called by muse, mutect2, varscan2
- ABLIM1 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs891214783; called by mutect2, varscan2
- ADAM12 | c.2288C>A p.P763H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1170725289; called by mutect2, varscan2
- ADAMTS12 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.273); catalogued as rs1275046910; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs952046590, COSV100417045; called by mutect2, varscan2
- ADGRG4 | c.4447G>T p.D1483Y | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54953975, COSV54964949; called by muse, mutect2, varscan2
- AHNAK2 | c.4151A>C p.D1384A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1292740743; called by mutect2, varscan2
- AMDHD1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs1415728144; called by muse, varscan2
- ANK2 | c.7054G>T p.G2352C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.391); catalogued as COSV52150780; called by muse, mutect2, varscan2
- ANKFN1 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59446983; called by muse, mutect2, varscan2
- ANKRD30A | c.1909G>T p.G637W (on ENST00000611781; = p.G581W on NM_052997.2) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV64605845; called by muse, mutect2, varscan2
- AP3B1 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 50/160 reads (31%) | catalogued as COSV54880515; called by muse, mutect2, varscan2
- ARHGAP5 | c.3193G>T p.G1065C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs140666572; called by muse, mutect2, varscan2
- ARID1B | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51670014; called by muse, mutect2, varscan2
- ATAD3A | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1338018303, COSV59235026; called by mutect2, varscan2
- ATP9A | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100125702, COSV58763316; called by muse, mutect2, varscan2
- BCLAF1 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV62142461; called by muse, mutect2, varscan2
- BTBD3 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs778264070; called by muse, mutect2, varscan2
- CACNA1B | c.4009C>T p.Q1337* | Nonsense Mutation (SNP) | VAF 33/53 reads (62%) | catalogued as rs1554753635; called by muse, mutect2, varscan2
- CALHM6 | c.887C>A p.T296K | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0.066); catalogued as COSV63991533; called by muse, mutect2, varscan2
- CAPZA1 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs1416998981, COSV99582917; called by muse, mutect2, varscan2
- CCDC168 | c.19889C>T p.P6630L | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1444015900; called by muse, mutect2, varscan2
- CCDC85A | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.038); catalogued as COSV68149366; called by muse, mutect2, varscan2
- CD1C | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV100939373, COSV63805841; called by muse, mutect2, varscan2
- CD300E | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); catalogued as rs780393497; called by muse, mutect2, varscan2
- CDH18 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56953112; called by muse, mutect2, varscan2
- CDH18 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV56908558; called by muse, mutect2, varscan2
- CDH23 | c.1205C>A p.P402Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs373168635; called by muse, varscan2
- CDH23 | c.4104G>T p.T1368= | Splice Region (SNP) | VAF 24/42 reads (57%) | catalogued as rs765658825; called by mutect2, varscan2
- CDHR1 | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs560256506; called by muse, mutect2, varscan2
- CHD7 | c.4424A>T p.E1475V | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as CD126767; called by muse, mutect2, varscan2
- CHST6 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.045); catalogued as rs752453536; called by muse, mutect2, varscan2
- CNTN5 | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 106/159 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54285671; called by muse, mutect2, varscan2
- COL14A1 | c.3878G>A p.R1293Q | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774792562, COSV52863776; called by muse, mutect2, varscan2
- COL9A1 | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs567381211, COSV61838018; called by muse, mutect2, varscan2
- COL9A3 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs145729725; called by mutect2, varscan2
- CPXM2 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.415); catalogued as COSV53868850; called by muse, mutect2, varscan2
- CR1 | c.3380G>T p.G1127V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1295120917, COSV65461638, COSV65461724; called by muse, mutect2, varscan2
- CSMD3 | c.1943G>T p.G648V (on ENST00000297405 / NM_001363185.1; = p.G544V on NM_052900.3) | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52131683; called by muse, mutect2, varscan2
- CXCL3 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56017935; called by muse, mutect2, varscan2
- DLX6 | c.876G>C p.M292I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as COSV99142192; called by muse, mutect2, varscan2
- DMP1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56819801; called by muse, mutect2, varscan2
- DMRT3 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as rs1174341638; called by mutect2, varscan2
- DNAH3 | c.6163C>T p.R2055W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780687704; called by muse, mutect2, varscan2
- DNAH5 | c.12761G>T p.R4254I | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54233097; called by muse, mutect2, varscan2
- DNAH5 | c.9013C>T p.Q3005* | Nonsense Mutation (SNP) | VAF 80/300 reads (27%) | catalogued as COSV54212802; called by muse, mutect2, varscan2
- DNAH6 | c.7660G>T p.E2554* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | catalogued as COSV52848269; called by muse, mutect2, varscan2
- DNM3 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1362768272; called by muse, mutect2, varscan2
- EGF | c.3032G>T p.R1011L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54475475; called by muse, mutect2, varscan2
- EIF5AL1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs990826285; called by mutect2, varscan2
- EPB41L3 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV59457028; called by muse, mutect2, varscan2
- ERBB4 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53526764; called by muse, mutect2, varscan2
- F11 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CD052108, COSV53009555; called by muse, mutect2, varscan2
- F13B | c.1353G>T p.L451F | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV66372455; called by muse, mutect2, varscan2
- F2RL2 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56972097; called by muse, mutect2, varscan2
- FAM155B | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52937877; called by muse, mutect2, varscan2
- FAM234A | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs375399489; called by muse, mutect2, varscan2
- FAM47B | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV61456246, COSV61456363; called by muse, mutect2, varscan2
- FAM47C | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63728700; called by muse, mutect2, varscan2
- FAM47C | c.644C>A p.P215Q | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63727717; called by muse, mutect2, varscan2
- FBN2 | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1284853055, COSV99325344; called by muse, mutect2, varscan2
- FGF20 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs778448883; called by mutect2, varscan2
- FOXD3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as rs531096085; called by mutect2, varscan2
- FREM2 | c.3899A>T p.D1300V | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265438116; called by muse, mutect2, varscan2
- GJB7 | c.126C>A p.H42Q | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV51531932; called by muse, mutect2, varscan2
- GNG2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58917511; called by muse, mutect2, varscan2
- GOT1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV65147032; called by mutect2, varscan2
- GRAMD1B | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59207838; called by mutect2, varscan2
- GSX2 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs754099416; called by mutect2, varscan2
- GUCY1A2 | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs748920637; called by muse, mutect2, varscan2
- HADHB | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 87/123 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs1357647406; called by muse, mutect2, varscan2
- HAO1 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV66491281; called by muse, mutect2, varscan2
- HDAC9 | c.1865C>A p.A622E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67765974; called by muse, mutect2, varscan2
- HEPH | c.2964G>T p.W988C (on ENST00000343002; = p.W721C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185884760; called by muse, mutect2, varscan2
- HEY2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1177812328; called by muse, mutect2, varscan2
- HGF | c.1514T>A p.I505K | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55957849; called by muse, mutect2, varscan2
- HMGCS2 | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV65568340, COSV65569522; called by muse, mutect2, varscan2
- IFI27L2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 64/118 reads (54%) | catalogued as COSV53128024; called by muse, mutect2, varscan2
- IL1RN | c.298G>T p.E100* (on ENST00000409930 / NM_173842.3; = p.E82* on NM_000577.5) | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV52079864; called by muse, mutect2, varscan2
- INHA | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV54717595; called by muse, mutect2, varscan2
- ITGA1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1003303207, COSV99251050; called by muse, mutect2, varscan2
- ITPR1 | c.6737G>A p.R2246Q (on ENST00000354582; = p.R2191Q on NM_002222.7) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1379481499, COSV56985398; called by muse, mutect2, varscan2
- JPH2 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV65905944; called by muse, mutect2, varscan2
- KCND2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV58608612; called by muse, mutect2, varscan2
- KLHL38 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV58086764; called by muse, mutect2, varscan2
- KRT27 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV56972981; called by muse, mutect2, varscan2
- KRTAP5-10 | c.217del p.D73Tfs*144 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV100924158; called by mutect2, varscan2
- LDB3 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53946767; called by mutect2, varscan2
- LINC02210-CRHR1 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.823); catalogued as rs768110046; called by muse, varscan2
- LIX1L | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs373283576; called by muse, mutect2, varscan2
- LMTK2 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1199825364, COSV51991672; called by muse, mutect2, varscan2
- LRFN5 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53243582; called by muse, mutect2, varscan2
- LRFN5 | c.2009G>T p.R670M | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV53254288; called by muse, mutect2, varscan2
- LRRC40 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV63942710; called by muse, mutect2, varscan2
- LRRFIP1 | c.1957G>A p.D653N (on ENST00000392000 / NM_001137552.2; = p.D629N on NM_004735.4) | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55253629; called by muse, mutect2, varscan2
- MACF1 | c.5245C>T p.R1749W | Missense Mutation (SNP) | VAF 34/135 reads (25%) | catalogued as rs565440734; called by muse, mutect2, varscan2
- MAGEB18 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV57463648; called by muse, mutect2, varscan2
- MARCHF1 | c.168C>A p.S56R (on ENST00000274056; = p.S39R on NM_017923.4) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs775801557; called by muse, mutect2, varscan2
- MARK2 | c.1736G>T p.G579V (on ENST00000402010 / NM_001039469.2; = p.G524V on NM_004954.5) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs770487182; called by mutect2, varscan2
- MCTP1 | c.1278C>A p.C426* | Nonsense Mutation (SNP) | VAF 48/69 reads (70%) | catalogued as rs376449269, COSV56528380; called by muse, mutect2, varscan2
- MDGA1 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1343605518; called by muse, mutect2, varscan2
- MPP2 | c.566C>A p.A189E (on ENST00000461854 / NM_001278372.2; = p.A165E on NM_005374.5) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52239909; called by mutect2, varscan2
- MUC12 | c.13422C>A p.S4474R (on ENST00000379442; = p.S4331R on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/569 reads (7%) | SIFT deleterious, low confidence (0.01); catalogued as rs1391383825; called by muse, mutect2
- MUC16 | c.27424A>T p.S9142C | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs1376206420; called by muse, varscan2
- MUC3A | c.2742G>T p.M914I | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.528); catalogued as rs1431308245; called by muse, mutect2, varscan2
- MXRA5 | c.5422A>G p.M1808V | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1470718112, COSV54224954; called by muse, mutect2, varscan2
- MYH6 | c.2462G>T p.R821L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62455015; called by muse, mutect2, varscan2
- MYOM2 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs770763914; called by muse, mutect2, varscan2
- NBPF14 | c.4703G>T p.R1568L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1410673050; called by muse, mutect2, varscan2
- NCKAP5 | c.4858G>T p.E1620* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV58433941; called by muse, mutect2
- NCKAP5 | c.2454G>T p.E818D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs768259994; called by muse, mutect2, varscan2
- NCOA1 | c.3108G>T p.M1036I | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56045416, COSV99947292; called by muse, mutect2, varscan2
- NRXN3 | c.3218G>A p.C1073Y (on ENST00000335750 / NM_001330195.2; = p.C700Y on NM_004796.6) | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59781165; called by muse, mutect2, varscan2
- NUTM1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1216220737; called by muse, mutect2, varscan2
- NXF5 | n.1445G>A | Splice Region (SNP) | VAF 20/27 reads (74%) | catalogued as COSV53790097; called by muse, mutect2, varscan2
- OR13C8 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV58611416; called by mutect2, varscan2
- OR14A2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63573579; called by muse, varscan2
- OR2F2 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1369816772; called by muse, mutect2, varscan2
- OR2M5 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV63546401; called by muse, mutect2, varscan2
- OR2T34 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs771392433, COSV60900190; called by muse, varscan2
- OR52B2 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs753034064; called by muse, mutect2, varscan2
- OR6C75 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV58553429; called by muse, mutect2, varscan2
- OR9Q1 | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 46/73 reads (63%) | catalogued as COSV59048198; called by muse, mutect2, varscan2
- OTOG | c.8669G>A p.R2890H | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375127426, COSV68039117; called by muse, mutect2, varscan2
- PADI2 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV100970943; called by mutect2, varscan2
- PARVB | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58691354; called by muse, mutect2, varscan2
- PCDH11X | c.2777C>A p.T926N | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV53454273; called by muse, mutect2, varscan2
- PCDH15 | c.2268G>T p.L756F | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100219567; called by muse, mutect2, varscan2
- PCDHGA3 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV99545412; called by muse, mutect2, varscan2
- PCDHGA3 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as rs1173251746; called by muse, mutect2, varscan2
- PCSK2 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV52741804; called by muse, mutect2, varscan2
- PKHD1 | c.7149G>T p.W2383C | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs757590581, COSV61871470; called by muse, mutect2, varscan2
- PLPP1 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as rs1429342726; called by muse, mutect2, varscan2
- POGLUT3 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60212639, COSV60212860; called by muse, mutect2, varscan2
- PPP1R3A | c.2840del p.S947Lfs*36 | Frame Shift Del (DEL) | VAF 45/126 reads (36%) | catalogued as COSV52879462, COSV52887391; called by mutect2, varscan2
- PRUNE2 | c.4846C>T p.R1616C | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs750530554, COSV65045488; called by muse, mutect2, varscan2
- PTCH1 | c.3908G>T p.R1303L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs779365332, COSV59500018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD4 | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59799237; called by muse, mutect2, varscan2
- RBM20 | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65704282; called by muse, mutect2, varscan2
- REG3A | c.371G>C p.S124T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV59409611; called by mutect2, varscan2
- RHBDD2 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV50086711; called by muse, mutect2, varscan2
- RNF175 | c.74A>T p.H25L | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99923950; called by muse, mutect2, varscan2
- RRP8 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as COSV99601938; called by muse, mutect2, varscan2
- SCG2 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV59541254; called by muse, mutect2, varscan2
- SCN2A | c.5407G>T p.E1803* | Nonsense Mutation (SNP) | VAF 82/159 reads (52%) | catalogued as rs1553463635, COSV51836678; called by muse, mutect2, varscan2
- SEMA5A | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs867495316; called by muse, mutect2, varscan2
- SEZ6L | c.1702T>A p.Y568N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99962277; called by muse, varscan2
- SF3B2 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs781167565; called by muse, varscan2
- SI | c.5057G>T p.R1686L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52283536; called by muse, mutect2, varscan2
- SIGLEC6 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as rs765487804, COSV58434023; called by muse, mutect2, varscan2
- SLC25A40 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100353614; called by muse, mutect2, varscan2
- SLITRK3 | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs540822976, COSV53846703; called by mutect2, varscan2
- SLITRK3 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53851894; called by muse, mutect2, varscan2
- STAT5A | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as rs1437867099, COSV61805944; called by muse, mutect2, varscan2
- SV2C | c.454T>C p.W152R | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754508238; called by muse, mutect2, varscan2
- TBC1D24 | c.1456C>A p.R486S (on ENST00000646147 / NM_001199107.2; = p.R480S on NM_020705.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV53547954; called by muse, mutect2, varscan2
- TENM4 | c.6424A>G p.T2142A | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781672573; called by muse, mutect2, varscan2
- TGIF2LY | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV100339721; called by muse, mutect2, varscan2
- TMEM132C | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs760872130, COSV101473472; called by muse, mutect2, varscan2
- TOGARAM1 | c.4691A>T p.H1564L | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV63894245; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRIM26 | c.1601G>C p.R534P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV70982647; called by muse, mutect2, varscan2
- TSHZ3 | c.3137G>T p.C1046F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53673041; called by muse, mutect2, varscan2
- TSHZ3 | c.1082C>A p.T361K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV53668629; called by muse, mutect2, varscan2
- TTN | c.29476G>A p.D9826N (on ENST00000591111; = p.D8899N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | PolyPhen probably damaging (0.998); catalogued as rs1553875406, COSV60195389; ClinVar: uncertain significance; called by mutect2, varscan2
- UNC5A | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99995143; called by muse, mutect2, varscan2
- UNC79 | c.4513G>T p.G1505W (on ENST00000393151 / NM_001346218.2; = p.G1328W on NM_020818.5) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56380381, COSV99830453; called by muse, mutect2, varscan2
- USH2A | c.5479G>T p.G1827* | Nonsense Mutation (SNP) | VAF 31/157 reads (20%) | catalogued as COSV56385811, COSV56419974; called by muse, mutect2, varscan2
- USP36 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs755107337; called by mutect2, varscan2
- VIRMA | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99889412; called by muse, mutect2, varscan2
- VWA2 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929413917; called by muse, mutect2, varscan2
- WDR49 | c.1072G>C p.G358R (on ENST00000308378 / NM_001366158.1; = p.G699R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57709774; called by muse, mutect2, varscan2
- XKR8 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs753843384; called by mutect2, varscan2
- XYLT1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1480839662; called by muse, mutect2, varscan2
- ZFHX4 | c.921C>G p.D307E | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50485623; called by muse, mutect2, varscan2
- ZNF716 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1554323322, COSV101348685; called by muse, mutect2, varscan2
- ZPLD1 | c.811C>T p.R271W (on ENST00000466937 / NM_001329788.1; = p.R287W on NM_175056.2) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.606); catalogued as rs147459423, COSV60352180; called by muse, mutect2, varscan2
- ABCB5 | c.2300G>T p.R767I (on ENST00000404938 / NM_001163941.2; = p.R322I on NM_178559.6) | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ABCC12 | c.1933T>A p.C645S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ABCF1 | c.822A>T p.L274F (on ENST00000326195 / NM_001025091.2; = p.L236F on NM_001090.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ABCG8 | c.1067T>C p.L356S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD6 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ACIN1 | c.2290C>G p.H764D | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ACSF2 | c.1768A>T p.T590S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS10 | c.1904del p.G635Afs*2 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- ADAMTS9 | c.1791T>A p.F597L | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ADCY8 | c.2514C>A p.F838L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADGB | c.2902A>T p.S968C | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ADGRG7 | c.1591G>C p.A531P | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADGRL3 | c.3930G>C p.M1310I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AEBP1 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by mutect2, varscan2
- AMPD1 | c.1860G>C p.M620I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANKRD13B | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ANKRD26 | c.3404G>T p.R1135I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ANKRD36 | c.3028A>T p.R1010* | Nonsense Mutation (SNP) | VAF 38/400 reads (10%) | called by muse, mutect2
- ANXA11 | c.1479C>A p.Y493* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- AP3B1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | called by muse, varscan2
- AP3B1 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- AP5Z1 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, varscan2
- APCDD1L | c.1497C>G p.H499Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.9969G>T p.L3323F | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ARMC3 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATAD2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ATAD2B | c.2963A>G p.D988G | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ATF5 | c.134dup p.A46Sfs*16 | Frame Shift Ins (INS) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- ATP10A | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP10D | c.1015+1del | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- ATP13A5 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- ATP2B3 | c.862del p.I288Sfs*47 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- ATRNL1 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ATRX | c.5612A>G p.K1871R | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AUTS2 | c.2338G>T p.G780C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, varscan2
- BAZ2B | c.3439G>T p.V1147L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- BCL2L13 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- BICC1 | c.1466G>T p.S489I | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- BLK | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BMP15 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- BMPR1B | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- BSDC1 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by mutect2, varscan2
- C10orf67 | c.844G>T p.G282* | Nonsense Mutation (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- C13orf42 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1QTNF3 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- C1orf167 | c.2604G>T p.Q868H | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- C2orf80 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- C8B | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- CACNA1E | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CACNA2D1 | c.1748G>T p.S583I (on ENST00000356253 / NM_001366867.1; = p.S564I on NM_000722.4) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CACNA2D4 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D4 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS2 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCT5 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CD1C | c.482G>C p.S161T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1E | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD69 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CDH22 | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- CDH8 | c.2391dup p.E798Rfs*9 | Frame Shift Ins (INS) | VAF 76/112 reads (68%) | called by mutect2, varscan2
- CEACAM8 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEMIP | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CEP128 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CEP162 | c.771A>T p.Q257H | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP44 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CFAP47 | c.2249T>C p.I750T | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by mutect2, varscan2
- CHP2 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CHST5 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by mutect2, varscan2
- CHST5 | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by mutect2, varscan2
- CIR1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- CLEC2L | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- CNTN2 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 135/212 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COIL | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- COL28A1 | c.2848A>G p.N950D | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL4A1 | c.3692C>A p.T1231K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); called by mutect2, varscan2
- COL4A6 | c.1791C>A p.F597L | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL5A2 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPLANE1 | c.8515C>T p.P2839S | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CROT | c.992A>G p.D331G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG2 | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.565); called by mutect2, varscan2
- CSMD1 | c.9802C>A p.Q3268K (on ENST00000520002; = p.Q3267K on NM_033225.6) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CSMD2 | c.8453G>A p.G2818E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- CSMD2 | c.586T>C p.C196R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CSMD3 | c.3930T>A p.F1310L (on ENST00000297405 / NM_001363185.1; = p.F1206L on NM_052900.3) | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CXCL3 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DAB2 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DCDC1 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- DGKB | c.959dup p.C321Vfs*2 | Frame Shift Ins (INS) | VAF 56/112 reads (50%) | called by mutect2, varscan2
- DIO2 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DLGAP4 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DMD | c.95T>A p.F32Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH12 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DNAH8 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DNAH8 | c.13419G>C p.L4473F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DNASE2B | c.183A>T p.L61F | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- DPP6 | c.2201C>A p.T734N (on ENST00000377770 / NM_001364500.2; = p.T672N on NM_001936.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DSC1 | c.1414C>A p.H472N | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG3 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- EFCAB5 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- EFR3A | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 111/196 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EIPR1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- EPB42 | c.40G>T p.A14S (on ENST00000441366 / NM_001114134.2; = p.A44S on NM_000119.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.355); called by mutect2, varscan2
- EPHA8 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ERMN | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ESPNL | c.1357G>C p.V453L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRB | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- EVX2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- EXO1 | c.1236G>T p.R412S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYA1 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- F2RL2 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- FAM71B | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2
- FAM71B | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2
- FANCL | c.5del p.A2Gfs*2 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- FAR2 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FAT3 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FAT3 | c.6954C>A p.N2318K | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT4 | c.12310G>T p.V4104F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBP1 | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FBXL19 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.104); called by mutect2, varscan2
- FCHSD2 | c.1041G>T p.R347= | Splice Region (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- FIGN | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- FLG | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FLG2 | c.3881C>A p.T1294K | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FOXL1 | c.763T>A p.S255T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by mutect2, varscan2
- FYB1 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FYB2 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABBR1 | c.1826G>C p.C609S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- GABRA4 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAPT | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- GATA3 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by mutect2, varscan2
- GBP1 | c.1246A>T p.S416C | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GP5 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GPRC5C | c.1186G>T p.A396S (on ENST00000652232; = p.A351S on NM_018653.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by mutect2, varscan2
- GRIN1 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GXYLT1 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, varscan2
- HADHA | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- HAUS5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HEXIM1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HGD | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- HMCN1 | c.2318T>C p.V773A | Missense Mutation (SNP) | VAF 95/175 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HMCN1 | c.5915G>T p.R1972I | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HPS1 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HPS6 | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by mutect2, varscan2
- HRG | c.619C>G p.H207D | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HTR3B | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HYAL4 | c.271T>G p.Y91D | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGKV1-8 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by mutect2, varscan2
- IL3 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IL9R | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IPMK | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB3 | c.1035G>A p.Q345= | Splice Region (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- IWS1 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KANSL3 | c.2170G>T p.A724S (on ENST00000666923 / NM_001349262.2; = p.A698S on NM_001115016.3) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KBTBD6 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- KCNG4 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNH5 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by mutect2, varscan2
- KCNH7 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KCNJ18 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.49); called by mutect2, varscan2
- KCNMA1 | c.2000C>A p.A667D | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNMB2 | c.520T>A p.C174S | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT2 | c.1174A>T p.R392W | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- KDR | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0586 | c.4300G>T p.D1434Y (on ENST00000619416 / NM_001244190.2; = p.D1373Y on NM_014749.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.377); called by mutect2, varscan2
- KIAA1109 | c.4172G>A p.S1391N | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIAA1549 | c.4413G>T p.R1471S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.219A>G p.I73M | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- KIR3DL1 | c.340dup p.V114Gfs*38 | Frame Shift Ins (INS) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- KMT2C | c.6158C>T p.S2053F | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- KNDC1 | c.3027G>T p.R1009S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRTAP10-2 | c.59A>C p.D20A | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.011); called by mutect2, varscan2
- KRTAP4-4 | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- LAMA5 | c.9199G>T p.G3067C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB4 | c.3310G>T p.G1104C | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCP2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- LIFR | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LIFR | c.1083G>T p.L361F | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- LIPM | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by mutect2, varscan2
- LOXHD1 | c.6226del p.D2076Tfs*85 (on ENST00000642948; = p.D2014Tfs*85 on NM_144612.7) | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | called by mutect2, varscan2
- LOXHD1 | c.3121A>G p.N1041D | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LRCH1 | c.1738A>T p.K580* | Nonsense Mutation (SNP) | VAF 54/78 reads (69%) | called by muse, mutect2, varscan2
- LRFN5 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.1956G>T p.L652F (on ENST00000392000 / NM_001137552.2; = p.L628F on NM_004735.4) | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LSM12 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LTBP1 | c.2806G>T p.G936* (on ENST00000404816 / NM_206943.4; = p.G610* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 53/88 reads (60%) | called by muse, mutect2, varscan2
- LTBP1 | c.2807G>T p.G936V (on ENST00000404816 / NM_206943.4; = p.G610V on NM_000627.4) | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- LYG1 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MALRD1 | c.4564A>G p.T1522A | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MAP3K21 | c.2464G>T p.V822L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by mutect2, varscan2
- MARK2 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MBTPS1 | c.2047A>T p.T683S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MCC | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MCF2 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MCM2 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MDC1 | c.5950C>A p.Q1984K | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- METTL26 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- MGAM2 | c.2047G>T p.G683* | Nonsense Mutation (SNP) | VAF 54/136 reads (40%) | called by muse, mutect2, varscan2
- MLLT10 | c.1588A>T p.S530C | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MMP16 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MOB4 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MOGAT3 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- MOGAT3 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MST1R | c.3368A>T p.Q1123L | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MSTN | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTTP | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MUC16 | c.26869C>A p.P8957T | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYH2 | c.1343dup p.Q449Afs*21 | Frame Shift Ins (INS) | VAF 62/98 reads (63%) | called by mutect2, varscan2
- MYH2 | c.430del p.R144Efs*24 | Frame Shift Del (DEL) | VAF 41/71 reads (58%) | called by mutect2, varscan2
- MYH6 | c.4813G>T p.A1605S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MYH8 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYO1G | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- NAA30 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.175); called by mutect2, varscan2
- NAV1 | c.1649C>A p.A550D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by mutect2, varscan2
- NCKAP5 | c.2020del p.E674Kfs*75 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, varscan2
- NDUFA10 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NEMF | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFKB1 | c.187G>T p.G63C (on ENST00000394820 / NM_001382627.1; = p.G64C on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NID2 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NPC1L1 | c.3787C>A p.Q1263K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NPHP1 | c.759A>T p.K253N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- NPLOC4 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR4A2 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP160 | c.1362A>T p.R454S | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- OBSCN | c.3864G>T p.E1288D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OGDHL | c.1713G>T p.W571C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OGDHL | c.1712G>A p.W571* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- OR11G2 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- OR1A1 | c.174del p.M59Cfs*18 | Frame Shift Del (DEL) | VAF 61/84 reads (73%) | called by mutect2, varscan2
- OR2L5 | c.693A>T p.E231D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by mutect2, varscan2
- OR2T2 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- OR4K3 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 85/331 reads (26%) | called by muse, mutect2, varscan2
- OR4K5 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OR51M1 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PAPPA2 | c.882del p.K294Nfs*54 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, varscan2
- PASK | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PBX3 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDHB6 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PDZD2 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PEAR1 | c.2383A>T p.S795C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PELP1 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT tolerated (0.15); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PIGC | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PIGC | c.847T>C p.W283R | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PKD1L1 | c.5893T>A p.C1965S | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PKHD1L1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PKLR | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- PKP3 | c.1637C>G p.A546G | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLEKHA7 | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLVAP | c.281_282insG p.K95Qfs*28 | Frame Shift Ins (INS) | VAF 9/13 reads (69%) | called by mutect2, varscan2
- PMP2 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP2 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POF1B | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- POTEA | c.1188G>C p.R396S (on ENST00000519951 / NM_001005365.2; = p.R350S on NM_001002920.1) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.155); called by muse, varscan2
- POTEG | c.982A>T p.N328Y | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- POU4F2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRLHR | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, varscan2
- PRM3 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- PROS1 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROSER1 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 60/81 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PSMD10 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- PTGER3 | c.1139C>A p.S380* | Nonsense Mutation (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- PTGS1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB44 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RALGAPB | c.3326G>T p.R1109L | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGRP3 | c.1500G>C p.M500I (on ENST00000402538 / NM_001349975.2; = p.M499I on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/148 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RAVER2 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBFOX1 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- RBM20 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RBM7 | c.56_60del p.T19Sfs*25 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, varscan2
- RBP3 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by mutect2, varscan2
- RCAN1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.48); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- REG3G | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.6835G>C p.E2279Q | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- RELN | c.198del p.Y67Tfs*10 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- RIMS4 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ROPN1 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPGRIP1 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RTTN | c.4565G>C p.G1522A | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RYR2 | c.5035C>A p.H1679N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RYR2 | c.8951C>A p.S2984Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SALL3 | c.2037C>A p.N679K | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SASS6 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by mutect2, varscan2
- SATB2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SC5D | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SCN5A | c.4552C>T p.Q1518* (on ENST00000333535 / NM_198056.3; = p.Q1517* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 31/42 reads (74%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SERPINA4 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SERPINE2 | c.1168T>A p.L390I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- SH2D4B | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SIGLEC7 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC22A12 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- SLC23A1 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SLC30A10 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SLC30A3 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- SLC4A1AP | c.79T>A p.L27M | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC6A5 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by mutect2, varscan2
- SLCO1C1 | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLFN14 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SMC3 | c.2694G>C p.Q898H | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- SORCS3 | c.3574C>G p.L1192V | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPANXN2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPATA31A7 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SPC24 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPHKAP | c.2915C>G p.P972R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SPHKAP | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SPP2 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ST6GAL2 | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 50/84 reads (60%) | PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- STAB2 | c.5075T>A p.V1692D | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- STYXL2 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STYXL2 | c.2586C>A p.D862E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SUGCT | c.1229A>C p.H410P (on ENST00000335693 / NM_001193313.2; = p.H436P on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SYCP1 | c.2134G>C p.A712P | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SYNE3 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TAS1R2 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- TAX1BP1 | c.2309A>G p.Q770R | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TDRD12 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TDRD3 | c.150T>A p.N50K | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TDRD5 | c.2244G>T p.Q748H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TENM1 | c.3347G>A p.W1116* | Nonsense Mutation (SNP) | VAF 25/33 reads (76%) | called by mutect2, varscan2
- TENM2 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.361); called by muse, varscan2
- TENM2 | c.7313C>A p.T2438N (on ENST00000518659 / NM_001122679.2; = p.T2199N on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TGM2 | c.1702G>C p.V568L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TJP1 | c.3837A>T p.L1279F | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- TMEM132D | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TMEM150B | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- TMEM161B | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM175 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TMEM201 | c.170T>A p.V57E | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNK2 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, varscan2
- TNS3 | c.3322del p.D1108Ifs*53 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, varscan2
- TPD52 | c.190A>G p.T64A (on ENST00000379097 / NM_001025252.3; = p.T24A on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TRBC1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- TTLL10 | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by mutect2, varscan2
- TTN | c.69532G>T p.D23178Y (on ENST00000591111; = p.D15754Y on NM_003319.4) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TTN | c.56643G>T p.R18881S (on ENST00000591111; = p.R11457S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTYH3 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBA1B | c.904A>T p.M302L | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TUBA3C | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TWIST1 | c.566T>A p.V189D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- TXNDC16 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- UGT1A7 | c.155_156dup p.H53Gfs*6 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- UGT2B17 | c.1012T>C p.W338R | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.3533G>T p.R1178M | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC79 | c.2453G>T p.G818V (on ENST00000393151 / NM_001346218.2; = p.G641V on NM_020818.5) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- USP15 | c.1592A>G p.H531R (on ENST00000280377 / NM_001351159.2; = p.H502R on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VEGFC | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VWA3B | c.2780A>T p.Q927L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); called by mutect2, varscan2
- WDR33 | c.4002_4003insT p.G1335Wfs*18 | Frame Shift Ins (INS) | VAF 23/38 reads (61%) | called by mutect2, varscan2
- WDR62 | c.4403G>T p.G1468V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); called by mutect2, varscan2
- WDR87 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WWP2 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- XIRP2 | c.1662del p.R556Efs*3 (on ENST00000628543; = p.R731Efs*3 on NM_152381.6) | Frame Shift Del (DEL) | VAF 44/85 reads (52%) | called by mutect2, varscan2
- XIRP2 | c.9056A>G p.K3019R (on ENST00000628543; = p.K3194R on NM_152381.6) | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR6 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZBTB44 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB49 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ZFHX4 | c.7531C>T p.H2511Y | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFPM2 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZFPM2 | c.2878C>A p.H960N | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF160 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF212 | c.1128G>T p.R376S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZNF536 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZNF583 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 46/58 reads (79%) | called by muse, mutect2, varscan2
- ZNF583 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF726 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF728 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF80 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF888 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 117/173 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZYG11A | c.1924C>A p.R642S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACAN | c.5754C>T p.P1918= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- ADGRA2 | c.2163T>A p.A721= | Silent (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2, varscan2
- AL441992.2 | c.189A>T p.P63= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, varscan2
- ANKRD50 | c.3057A>T p.A1019= | Silent (SNP) | VAF 49/76 reads (64%) | called by muse, mutect2, varscan2
- APOB | c.8121C>A p.T2707= | Silent (SNP) | VAF 122/204 reads (60%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.2343G>T p.G781= (on ENST00000289968 / NM_001006634.3; = p.G703= on NM_018054.6) | Silent (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.126C>T p.F42= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs772729752, COSV68334760; called by muse, mutect2, varscan2
- ARHGEF17 | c.2859C>T p.S953= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs201103249; called by mutect2, varscan2
- ARHGEF18 | c.999A>G p.Q333= (on ENST00000359920 / NM_001130955.2; = p.Q229= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs1297886437; called by muse, mutect2, varscan2
- ARID3C | c.1011C>T p.P337= | Silent (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- ARID5B | c.3231C>T p.I1077= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1343745122, COSV54413835; called by muse, mutect2, varscan2
- ATR | c.6813A>T p.P2271= | Silent (SNP) | VAF 90/204 reads (44%) | catalogued as rs774286189; called by muse, mutect2, varscan2
- BPIFB4 | c.1326G>T p.L442= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- C4orf45 | c.516T>A p.P172= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- CAD | c.4095C>T p.H1365= | Silent (SNP) | VAF 13/27 reads (48%) | called by mutect2, varscan2
- CANT1 | c.702G>A p.T234= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1023756732; called by muse, mutect2
- CCDC172 | c.96C>A p.T32= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- CEBPG | c.333G>T p.L111= | Silent (SNP) | VAF 82/206 reads (40%) | called by muse, mutect2, varscan2
- CHAT | c.1614C>T p.A538= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs1171598826; called by muse, mutect2, varscan2
- CHRNB2 | c.12C>A p.R4= | Silent (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- COPS4 | c.618A>G p.Q206= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as rs757511849; called by muse, mutect2, varscan2
- CPNE4 | c.87T>A p.R29= | Silent (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- CRACD | c.2751G>T p.R917= | Silent (SNP) | VAF 12/37 reads (32%) | called by mutect2, varscan2
- CRTAC1 | c.1017C>T p.F339= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.552C>T p.P184= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs971457055; called by mutect2, varscan2
- DNAH17 | c.5274C>T p.T1758= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs751171781; called by muse, mutect2, varscan2
- DNAH7 | c.4299G>T p.G1433= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- DNAH9 | c.10080G>T p.V3360= | Silent (SNP) | VAF 42/54 reads (78%) | called by muse, mutect2, varscan2
- DPP6 | c.2202C>A p.T734= (on ENST00000377770 / NM_001364500.2; = p.T672= on NM_001936.5) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs763606808; called by muse, mutect2, varscan2
- DSP | c.4674G>C p.R1558= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- ECI2 | c.75G>T p.P25= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV60985244; called by mutect2, varscan2
- EHBP1L1 | c.1983A>T p.S661= | Silent (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- EYA1 | c.903G>T p.G301= | Silent (SNP) | VAF 61/196 reads (31%) | catalogued as COSV58171383; called by muse, mutect2, varscan2
- EYS | c.522C>T p.C174= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as rs373343831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM171A2 | c.2379G>A p.P793= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs961168961; called by muse, mutect2, varscan2
- FAM83H | c.1773C>T p.H591= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1379795293; called by muse, varscan2
- FARSB | c.54C>T p.T18= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.13749A>T p.P4583= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- FBXW12 | c.297G>T p.T99= | Silent (SNP) | VAF 22/31 reads (71%) | called by mutect2, varscan2
- FER1L6 | c.4047G>T p.P1349= | Silent (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- FGF8 | c.396G>T p.G132= (on ENST00000344255 / NM_033164.4; = p.G114= on NM_006119.6) | Silent (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- FGR | c.669G>A p.V223= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs112532222; called by muse, mutect2, varscan2
- FITM2 | c.477G>T p.L159= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- FYTTD1 | c.171C>T p.L57= | Silent (SNP) | VAF 105/191 reads (55%) | catalogued as rs747761697; called by muse, mutect2, varscan2
- GAS8 | c.1434G>A p.T478= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs375085177; called by muse, mutect2, varscan2
- GNG7 | c.165G>T p.S55= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs770566550; called by muse, mutect2, varscan2
- GOLGB1 | c.3564G>A p.K1188= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- GP2 | c.828C>A p.T276= (on ENST00000381362 / NM_001007240.3; = p.T273= on NM_001502.4) | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV56892897; called by muse, mutect2, varscan2
- GRAMD1B | c.1824G>T p.P608= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100455020; called by muse, mutect2
- HERC5 | c.1344A>T p.A448= | Silent (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- HGF | c.816T>C p.Y272= | Silent (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- HTR3E | c.498C>A p.I166= (on ENST00000415389 / NM_001256613.1; = p.I181= on NM_182589.2) | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- IARS1 | c.213T>C p.Y71= | Silent (SNP) | VAF 62/89 reads (70%) | called by muse, mutect2, varscan2
- ITPR2 | c.6318C>T p.H2106= | Silent (SNP) | VAF 50/77 reads (65%) | called by muse, mutect2, varscan2
- KIAA1755 | c.3099A>G p.L1033= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs765732008; called by mutect2, varscan2
- KLF18 | c.1368C>A p.T456= | Silent (SNP) | VAF 38/180 reads (21%) | called by muse, varscan2
- LRFN3 | c.240C>A p.A80= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- LRP5 | c.2166C>T p.G722= | Silent (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- LRRC9 | c.2895C>A p.L965= | Silent (SNP) | VAF 29/110 reads (26%) | called by mutect2, varscan2
- MAG | c.1440C>A p.A480= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- MAP7D1 | c.252A>G p.E84= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs772277110; called by mutect2, varscan2
- MCF2L2 | c.2433G>A p.V811= | Silent (SNP) | VAF 66/183 reads (36%) | called by muse, mutect2, varscan2
- MSI1 | c.915G>A p.G305= | Silent (SNP) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- MUC2 | c.768G>C p.R256= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- MUC5AC | c.6228C>A p.T2076= | Silent (SNP) | VAF 31/164 reads (19%) | called by muse, varscan2
- MXRA5 | c.8019C>A p.L2673= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV54238387; called by muse, mutect2, varscan2
- MYF5 | c.522C>A p.V174= | Silent (SNP) | VAF 51/81 reads (63%) | called by muse, mutect2, varscan2
- MYO16 | c.384G>C p.T128= | Silent (SNP) | VAF 59/82 reads (72%) | called by muse, mutect2, varscan2
- OCA2 | c.1458C>T p.D486= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as COSV62353284; called by muse, mutect2, varscan2
- OPN5 | c.909C>A p.P303= | Silent (SNP) | VAF 21/103 reads (20%) | called by mutect2, varscan2
- OR10K2 | c.15T>C p.N5= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- OR2G3 | c.555C>G p.L185= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV60683249; called by muse, mutect2, varscan2
- OR2T27 | c.21C>A p.S7= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV100788290; called by muse, mutect2, varscan2
- OVCH1 | c.345A>G p.Q115= | Silent (SNP) | VAF 52/81 reads (64%) | called by muse, mutect2, varscan2
- PASK | c.726C>T p.V242= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1308878029; called by muse, mutect2, varscan2
- PCDHA3 | c.1509G>T p.A503= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV63540090; called by mutect2, varscan2
- PDE6B | c.660G>T p.L220= | Silent (SNP) | VAF 18/29 reads (62%) | called by mutect2, varscan2
- PDGFD | c.210G>T p.P70= | Silent (SNP) | VAF 66/396 reads (17%) | catalogued as COSV56381269; called by muse, mutect2, varscan2
- PIEZO1 | c.99C>G p.V33= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1241374574; called by muse, varscan2
- PKHD1 | c.3225C>A p.P1075= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV61894423; called by muse, mutect2, varscan2
- PKHD1L1 | c.8358T>A p.A2786= | Silent (SNP) | VAF 98/171 reads (57%) | called by muse, mutect2, varscan2
- PLD5 | c.594C>A p.A198= (on ENST00000442594; = p.A136= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2
- PPFIA3 | c.2721C>G p.P907= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- PRKD1 | c.939A>T p.A313= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as COSV59559630; called by muse, mutect2, varscan2
- PTPRN | c.1209C>A p.A403= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- QARS1 | c.1473T>C p.Y491= | Silent (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- RALYL | c.99C>A p.V33= | Silent (SNP) | VAF 89/306 reads (29%) | catalogued as COSV72823202; called by muse, mutect2, varscan2
- RANBP2 | c.4746C>G p.A1582= | Silent (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- RDH8 | c.717C>A p.L239= (on ENST00000651512; = p.L219= on NM_015725.4) | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- RNF113B | c.841C>T p.L281= | Silent (SNP) | VAF 20/36 reads (56%) | called by mutect2, varscan2
- RPE65 | c.700C>A p.R234= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as CM971315, COSV52018230; called by muse, mutect2, varscan2
- RYR2 | c.11188C>A p.R3730= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.14265C>A p.T4755= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- SERPINA9 | c.972G>A p.K324= | Silent (SNP) | VAF 43/176 reads (24%) | called by muse, mutect2
- SGK2 | c.342C>A p.R114= | Silent (SNP) | VAF 15/43 reads (35%) | called by mutect2, varscan2
- SLC24A4 | c.297C>A p.A99= | Silent (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- SLFN11 | c.2112C>T p.Y704= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs745463165; called by muse, mutect2, varscan2
- SND1 | c.1074G>T p.V358= | Silent (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- SORL1 | c.3321C>T p.S1107= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs377519209; called by muse, mutect2, varscan2
- SRGAP3 | c.288G>A p.V96= | Silent (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- ST7L | c.414G>A p.R138= | Silent (SNP) | VAF 25/120 reads (21%) | called by mutect2, varscan2
- STX2 | c.744A>G p.E248= | Silent (SNP) | VAF 42/67 reads (63%) | called by muse, mutect2, varscan2
- SYNJ2 | c.2175C>T p.G725= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs773873405, COSV62895458; called by muse, mutect2, varscan2
- SYT16 | c.585C>A p.I195= | Silent (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- TAF11L13 | c.375G>A p.L125= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- TAF1L | c.1311G>T p.G437= | Silent (SNP) | VAF 68/155 reads (44%) | called by muse, mutect2, varscan2
- TEP1 | c.4305G>T p.L1435= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1393820969, COSV99401353; called by muse, mutect2, varscan2
- TEX15 | c.1071C>A p.A357= (on ENST00000256246; = p.A740= on NM_001350162.2) | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99821989; called by muse, mutect2, varscan2
- TNS3 | c.1035G>C p.T345= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, varscan2
- TRBV18 | c.307C>A p.R103= | Silent (SNP) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- TRBV5-3 | c.309G>T p.G103= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1176G>T p.G392= | Silent (SNP) | VAF 20/55 reads (36%) | called by mutect2, varscan2
- TTC12 | c.2094G>T p.T698= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as COSV59097988, COSV59098715; called by muse, mutect2, varscan2
- TTN | c.3423G>T p.L1141= (on ENST00000591111; = p.L1095= on NM_003319.4) | Silent (SNP) | VAF 74/138 reads (54%) | catalogued as COSV100620705; called by muse, mutect2, varscan2
- TYR | c.1155C>A p.I385= | Silent (SNP) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- UNC13C | c.3894G>A p.K1298= | Silent (SNP) | VAF 70/111 reads (63%) | catalogued as rs763479014; called by muse, mutect2, varscan2
- UNC93A | c.744T>A p.T248= | Silent (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- UPK3A | c.18C>A p.A6= | Silent (SNP) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- USP5 | c.1530G>A p.R510= | Silent (SNP) | VAF 27/37 reads (73%) | called by muse, mutect2, varscan2
- VIT | c.1875G>T p.A625= (on ENST00000389975 / NM_001177969.1; = p.A640= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV64899801; called by muse, mutect2, varscan2
- WDFY2 | c.657A>T p.S219= | Silent (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- WDR87 | c.1926C>A p.A642= | Silent (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- WNT4 | c.81C>T p.Y27= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- XYLT1 | c.2869C>A p.R957= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV54493472; called by mutect2, varscan2
- ZFP91 | c.1569G>T p.T523= | Silent (SNP) | VAF 41/66 reads (62%) | called by muse, mutect2, varscan2
- ZIC1 | c.597C>A p.P199= | Silent (SNP) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- ZNF423 | c.3801C>T p.Y1267= (on ENST00000563137 / NM_001379286.1; = p.Y1259= on NM_015069.4) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs773714654; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF718 | c.435T>G p.S145= | Silent (SNP) | VAF 48/57 reads (84%) | called by muse, mutect2, varscan2
- ZNF862 | c.2175G>T p.V725= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2
- ZSWIM8 | c.678G>T p.R226= | Silent (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- AL354685.1 | n.108C>A | RNA (SNP) | VAF 28/44 reads (64%) | called by mutect2, varscan2
- ARHGEF4 | chr2:130915960 G>T | 5'Flank (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- ASCC3 | chr6:100881598 del T | 5'Flank (DEL) | VAF 26/39 reads (67%) | called by mutect2, varscan2
- ATP11AUN | n.903C>T | RNA (SNP) | VAF 4/22 reads (18%) | catalogued as rs746932458; called by mutect2, varscan2
- C1QTNF3 | c.84+215G>T | Intron (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- CCN5 | c.*282C>A | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CLEC16A | c.2641+9994A>G | Intron (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- DDR2 | c.1504+151C>A | Intron (SNP) | VAF 43/104 reads (41%) | catalogued as rs772480072; called by muse, mutect2, varscan2
- DNAH12 | c.6930-5047T>A | Intron (SNP) | VAF 59/77 reads (77%) | called by muse, mutect2, varscan2
- DST | c.4297-1860C>T | Intron (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- FLNB | c.4391-789G>T | Intron (SNP) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- GLRA4 | c.933+79C>A | Intron (SNP) | VAF 22/30 reads (73%) | catalogued as rs780487254; called by muse, mutect2, varscan2
- IGHG1 | chr14:105740142 C>A | 3'Flank (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- IL13RA1 | c.1010-3326A>T | Intron (SNP) | VAF 15/19 reads (79%) | called by muse, mutect2
- KCNIP4 | c.61+251143T>A | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- LRRC6 | c.11-37G>T | Intron (SNP) | VAF 45/183 reads (25%) | called by muse, mutect2, varscan2
- LRRC6 | c.11-38G>A | Intron (SNP) | VAF 45/184 reads (24%) | catalogued as rs749657515; called by muse, mutect2, varscan2
- LYZL2 | c.*5G>T | 3'UTR (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*785G>T | 3'UTR (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- MGAM | c.4618+264T>A | Intron (SNP) | VAF 52/150 reads (35%) | called by muse, mutect2, varscan2
- MRPL36 | chr5:1801341 T>A | 5'Flank (SNP) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- PFKL | c.86-830A>C | Intron (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- PRKD2 | c.-669G>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- RNU6-1178P | chr17:20895750 C>A | 5'Flank (SNP) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- SERPINA10 | c.-51+518G>A | Intron (SNP) | VAF 15/68 reads (22%) | catalogued as rs1405012983; called by muse, mutect2, varscan2
- SLC38A5 | c.*193C>G | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12848G>T | Intron (SNP) | VAF 29/50 reads (58%) | called by mutect2, varscan2
- SLCO4A1 | n.224G>A | RNA (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+207G>T | Intron (SNP) | VAF 39/115 reads (34%) | catalogued as rs1242664006; called by muse, mutect2, varscan2
- TEPP | c.785+357G>A | Intron (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- TP63 | c.325-18466G>T | Intron (SNP) | VAF 95/183 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.10360+5175G>A | Intron (SNP) | VAF 51/98 reads (52%) | catalogued as COSV100619190; called by muse, mutect2, varscan2
- TTN | c.10303+2418C>T | Intron (SNP) | VAF 47/109 reads (43%) | catalogued as rs867808369; called by muse, mutect2, varscan2
- VSTM1 | c.355+2785G>T | Intron (SNP) | VAF 26/27 reads (96%) | called by muse, mutect2, varscan2
- XIRP2 | c.-33G>T | 5'UTR (SNP) | VAF 67/130 reads (52%) | catalogued as COSV54737673; called by muse, mutect2, varscan2
- ZDHHC11 | c.784+129C>A | Intron (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- ZNF385B | c.715+2244G>C | Intron (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- ZNF729 | c.-85G>T | 5'UTR (SNP) | VAF 17/40 reads (43%) | catalogued as rs191820372; called by muse, mutect2, varscan2
- ZNF827 | c.*168G>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
